Surgical pathology report (de-identified scan), TCGA case TCGA-A4-A4ZT, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-A4ZT-01A (Primary Tumor).

[page 1 of 3]
Gender: F

Date of Service: Date Received:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

KIDNEY, LEFT, NEPHRECTOMY:

- PAPILLARY RENAL CELL CARCINOMA, SEE COMMENT.
- FUHRMAN NUCLEAR GRADE 3.
- TUMOR SIZE: 6 CM.
- LIMITED TO KIDNEY.
- SURGICAL MARGINS NEGATIVE.

1C1A-0-3

carcinoma, papillary renal cell

8260/3

Site: Kidney, NOS C64.9

hw

11/4/12

PATHOLOGIC TUMOR STAGING SYNOPSIS (LEFT KIDNEY):

Type and grade: Papillary renal cell carcinoma, Fuhrman nuclear grade 3.

Primary tumor: pT1b.

Regional lymph node: pNX.

Distant metastasis: N/A.

Pathologic stage: I.

Lymphovascular invasion: Not identified.

Margin status: R0, negative.

COMMENT: Sections of the tumor show a papillary renal cell carcinoma with a predominantly type I histologic pattern with Fuhrman nuclear grade 1 nuclei, however, there are focal areas with Fuhrman grade 3 nuclei with a type II architectural pattern.

Kidney Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, June 2012.

Page 1

This report continues... (FINAL)

[page 2 of 3]
Patient:

Case #:

Procedure:	Radical nephrectomy.
Specimen laterality:	Left.
TUMOR FEATURES:	
Tumor size:	6 cm.
Tumor focality:	Single focus.
Macroscopic extent of tumor:	Limited to kidney.
Histologic type:	Papillary renal cell carcinoma.
Sarcomatoid features:	Not identified.
Histologic grade:	Fuhrman nuclear grade 3.
Microscopic tumor extension:	Limited to kidney.
MARGINS:	R0, negative.
LYMPH NODES:	Not identified.
PATHOLOGIC STAGING:	
Primary tumor:	pT1b.
Regional lymph nodes:	pNX.
Distant metastasis:	N/A.
Pathologic stage:	I.
Pathologic findings in non-neoplastic kidney:	Interstitial chronic inflammation.

Source of Specimen:

Page 2

This report continues... (FINAL)

[page 3 of 3]
Patient:

Case #

FINAL SURGICAL PATHOLOGY REPORT

Kidney, Left

Clinical History/Operative Dx:

Renal mass

Gross Description:

The specimen is labeled left kidney and is received without fixative. It consists of a nephrectomy specimen which together perinephric fat weighs 627 grams. It measures 20 cm from superior to inferior, 10 cm from medial to lateral, and 9 cm from anterior to posterior. Along the anterior surface there is lobulated fatty tissue and there is a bulging fluctuant mass at the inferior pole of the kidney. At the hilum the renal artery and renal vein are identified. The vessels are opened and show no gross evidence of intraluminal tumor. Extending from the hilum of the kidney there is an 8 cm segment of ureter which appears somewhat attenuated. The ureter is opened to reveal smooth tan-white urothelium. The kidney is bivalved to reveal a fluid filled cystic mass in the inferior pole which bulges anteriorly this cystic mass measures 6 x 6 x 5.2 cm. It contains amorphous brown material and turbid fluid. The lining of the cyst is brown with patchy small areas of yellow discoloration. The cyst is 1.3 cm from the hilum of the kidney. It appears contained within the renal capsule and is separated from the anterior surface of the kidney by a thin layer of smooth fascial tissue. Representative sections of the mass are obtained for research purposes. The remaining kidney has pale red parenchyma and normal appearing medullary rays. Cortical thickness is 0.6 cm. There are scattered fluid filled cysts within the cortical portion of the kidney which are up to 1.3 cm. No other discrete masses are present. Serial sections of the perineural adipose tissue reveal no grossly obvious lymph nodes and no identifiable adrenal tissue. Representative sections are submitted.

Section summary:

- A1) surgical margin, renal artery, renal vein and ureter,
- A2) additional sections of ureter and ureteral pelvic junction,
- A3) anterior surface of lower pole kidney including possible Gerota's fascia,
- A4-A6) additional representative sections of cyst,
- A7) cyst and closest approach to hilum,
- A8) uninvolved kidney.

Microscopic Description:

Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

An intradepartmental consultation with [REDACTED] office notified of result

Reviewed Initials [REDACTED]	Date Reviewed: 11/14/12	

Page 3

END OF REPORT (FINAL)

Source: NCI Genomic Data Commons file 6905f8c4-bbda-4c14-be5a-b0858a47a6f3 (TCGA-A4-A4ZT.34F6C188-BEEA-42B6-BF31-5A3E351C6AA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).